Surgical pathology report (de-identified scan), TCGA case TCGA-BF-A5ES, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-A5ES-01A (Primary Tumor).

Index	Cureline Specimen label	Clinical Site #	Case #	DOB (mm/dd/yyyy)	Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container	Unit	Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)	Tumor cell %
					Female	Caucasian (White)	Melanoma		Skin	Primary	Tumor	Tissue	OCT	block	1	200	mg	surgery	Melanoma	n/a	4	0	N/A	none	n/a	80
					Female	Caucasian (White)	Melanoma		Blood	n/a	Normal	Blood	frozen	tube	1	4	ml	blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

Trunk, per TSS.

ICD-O-3

Melanoma, malignant NOS
8720/3

Site: Skin trunk
C44.5

per 4/2/13

Criteria	per 12/21/12	Yes	No

Source: NCI Genomic Data Commons file ed61d910-f7fc-4ef2-86bc-bdf1f92ba80d (TCGA-BF-A5ES.89406688-2097-4F89-ADC3-414894203BC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).